TARGET case TARGET-50-PAJNYM — High-Risk Wilms Tumor (TARGET-WT)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Complex Mixed and Stromal Neoplasms; Primary site: Kidney. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/11335db6-eb67-5094-be42-e2ffa4998a9f

Demographics
Sex at birth: female; Age at index: 0 years; Vital status: Dead; Days to death: 131 days; Cause of death: Toxicity.

Diagnoses (1)
1. Wilms tumor: ICD-O-3 morphology code: 8960/3; ICD-10 code: C64; Tissue or organ of origin: Kidney, NOS; Classification of tumor: primary; Age at diagnosis: 0.9 years (327 days); Year of diagnosis: 2000; Days to last follow up: 131 days; Pediatric kidney staging: Nephrectomy specimen with tumor confined to the kidney, no distant metastasis; Wilms tumor histologic subtype: Favorable.
   Treatment given: Protocol identifier: NWTS-5.

Follow-up (1 entry)
- Days to follow up: 131 days; Days to first event: 131 days; First event: Progression; Year of follow up: 2000.

Biospecimens (1 sample)
- Sample TARGET-50-PAJNYM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.

Additional fields from the TARGET clinical supplement workbook TARGET_WT_ClinicalData_Validation_20230322.xlsx (sheet Clinical Data):
- Overall Survival Time in Days: 131
- Stage: I
- ICD-O-3-T: C649
- Histologic Classification of Primary Tumor: FHWT
